TCGA case TCGA-77-8150 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Prince Charles Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7cc8892e-4ba5-4cf5-be76-9e5cb4891d25

Demographics
Sex at birth: male; Country of residence at enrollment: Australia; Age at index: 64 years; Vital status: Dead; Days to death: 1,655 days (4.5 years).

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.9; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 64.3 years (23,474 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,655 days (4.5 years); Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 67.8 years (24,752 days); Days to diagnosis: 1,278 days (3.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.
3. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 68.3 years (24,930 days); Days to diagnosis: 1,456 days (4.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 1,278 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 1,278 days (3.5 years); Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Day 1,456 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 1,456 days (4.0 years).
- Days to follow up: 1,655 days (4.5 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Preoperative.

Other clinical attributes
- DLCO (% of predicted): 73; FEV1/FVC before bronchodilator (%): 59.6; FEV1 before bronchodilator (% of reference): 59.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 46; Tobacco smoking onset year: 1961.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-77-8150-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.8; Shortest dimension: 0.5.
  Slide TCGA-77-8150-01A-01-TS1: Section location: Top; Percent tumor nuclei: 65; Percent necrosis: 0.
- Sample TCGA-77-8150-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-77-8150-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 2; Anatomic organ subdivision: R-Lower; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,655 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,655 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,278 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-77-8150-01A-11D-2243-01): tumor purity 0.56, ploidy 3.72, whole-genome doublings 1.
